Somatic mutation profile of tumor specimen 0DUIYN from CCDI case PBCLDW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.7 years (2,454 days).
Specimen 0DUIYN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfb744af-70f3-42f9-8737-f033234c6e3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUIWO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e874f418-b0b0-49a0-94a5-c2577cef9f76

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 100/338 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- FAM234B | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 187/559 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.356); catalogued as rs976381986; called by muse, mutect2, varscan2
- PDGFRA | c.1686_1687insTGGGTCATT p.I562_E563insWVI | In Frame Ins (INS) | VAF 150/472 reads (32%) | called by mutect2, varscan2
- PPFIA2 | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 154/407 reads (38%) | called by muse, mutect2, varscan2
